Somatic mutation profile of tumor specimen TCGA-DK-A3WX-01A (aliquot TCGA-DK-A3WX-01A-22D-A22Z-08) from TCGA case TCGA-DK-A3WX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,553 days).
Specimen TCGA-DK-A3WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a97f4cb-280c-43e0-a021-a7e3bf293a12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3WX-10A (Blood Derived Normal), aliquot TCGA-DK-A3WX-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a483cb-635d-423f-ab04-871de4b2c828

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Del 5, 5'Flank 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4364A>G p.Q1455R | Missense Mutation (SNP) | VAF 20/118 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54333839; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAT2 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52794234; called by muse, mutect2, varscan2
- BAZ1A | c.3658G>C p.D1220H | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); catalogued as COSV62410914; called by muse, mutect2, varscan2
- CCDC82 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV53594251; called by muse, varscan2
- CEACAM18 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs200987432; called by muse, mutect2, varscan2
- CNTNAP2 | c.1670+1G>A p.X557_splice | Splice Site (SNP) | VAF 16/140 reads (11%) | catalogued as rs1300862379, COSV62211094; called by muse, mutect2, varscan2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by muse, mutect2, varscan2
- EHMT2 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV64996803; called by muse, mutect2, varscan2
- FLRT3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs147588771; called by muse, mutect2
- GTF2E1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV52205074; called by muse, mutect2
- HDAC7 | c.2809G>A p.D937N (on ENST00000427332; = p.D976N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV50385624; called by muse, mutect2, varscan2
- KATNA1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as COSV59503114; called by muse, mutect2
- MAGEC1 | c.2758C>T p.L920F | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53576388; called by muse, mutect2, varscan2
- MBD1 | c.1129T>C p.C377R (on ENST00000269468 / NM_001323950.1; = p.C354R on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54003687; called by muse, varscan2
- MN1 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV56558292; called by muse, mutect2, varscan2
- NADSYN1 | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768545737, COSV59813251; called by muse, mutect2, varscan2
- OR4N5 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs139546094; called by muse, mutect2, varscan2
- PPP4R3B | c.2064G>C p.Q688H (on ENST00000616407 / NM_001122964.3; = p.Q603H on NM_020463.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as COSV55406541; called by muse, mutect2, varscan2
- RRP9 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV51755319; called by muse, mutect2, varscan2
- SCN10A | c.5049del p.N1684Tfs*14 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as COSV101479224; called by mutect2, pindel, varscan2
- TIMM17B | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781920385, COSV54430984; called by muse, mutect2, varscan2
- TOP2B | c.158G>A p.R53K (on ENST00000264331 / NM_001330700.2; = p.R48K on NM_001068.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV51973999; called by muse, mutect2, varscan2
- TP53INP1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV61332075; called by muse, mutect2, varscan2
- TRIO | c.6748A>G p.I2250V | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369327322, COSV59991098; called by muse, mutect2, varscan2
- WASHC5 | c.977del p.Q326Rfs*20 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as COSV59198059; called by mutect2, pindel, varscan2
- ZBTB9 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV67702216; called by muse, mutect2, varscan2
- ZC3H3 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs778193896; called by muse, mutect2
- ZMIZ2 | c.1790C>A p.S597Y | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV54809335; called by muse, mutect2, varscan2
- ACAT1 | c.1032dup p.E345Rfs*10 | Frame Shift Ins (INS) | VAF 39/211 reads (18%) | called by mutect2, pindel, varscan2
- CLIP3 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSDE1 | c.1306_1324del p.A436Kfs*25 (on ENST00000358528 / NM_001007553.3; = p.A405Kfs*25 on NM_007158.6) | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- GRK1 | c.949_964del p.D317Tfs*64 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel*
- MRC1 | c.2319C>A p.N773K | Missense Mutation (SNP) | VAF 42/385 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPIB | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.935); called by muse, mutect2
- TP53 | c.1043_1057delinsGGAA p.L348Wfs*30 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by pindel, varscan2*
- ABCB5 | c.1407A>G p.Q469= (on ENST00000404938 / NM_001163941.2; = p.Q24= on NM_178559.6) | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV51713447; called by muse, mutect2, varscan2
- EHD4 | c.1410C>T p.A470= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV55005674; called by muse, mutect2, varscan2
- EHMT2 | c.2181G>A p.V727= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as COSV64996788; called by muse, mutect2, varscan2
- GALNT2 | c.1059G>A p.P353= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs770283690, COSV64196021; called by muse, mutect2, varscan2
- HECTD3 | c.858G>A p.K286= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV55801046; called by muse, mutect2, varscan2
- KATNA1 | c.171G>A p.Q57= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV59503122; called by muse, mutect2
- KCNA2 | c.294G>A p.L98= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV60370756, COSV60371596, COSV60371813; called by muse, mutect2, varscan2
- MYBL1 | c.123C>T p.D41= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs747299413, COSV72919067; called by muse, mutect2, varscan2
- ZMYM1 | c.2283A>C p.V761= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV63252435; called by muse, mutect2, varscan2
- ZNF536 | c.1248C>T p.G416= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1210438094, COSV62821178, COSV62823770; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.838C>T | RNA (SNP) | VAF 14/78 reads (18%) | catalogued as rs560640153; called by muse, mutect2, varscan2
- PTEN | c.-1C>T | 5'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as rs770965327, COSV100911534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTS2 | chr1:7853402 G>A | 5'Flank (SNP) | VAF 21/117 reads (18%) | catalogued as rs138271613; called by muse, mutect2, varscan2
